Somatic mutation profile of tumor specimen HCM-CSHL-0075-C25-01B (aliquot HCM-CSHL-0075-C25-01B-11D-A78L-36) from HCMI case HCM-CSHL-0075-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 74.8 years (27,321 days).
Specimen HCM-CSHL-0075-C25-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b1898f8-6578-4bdb-b9db-e332cbee1192.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0075-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0075-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a7f3506-8852-47d8-8bd2-f6f6687ce124

The open-access MAF lists 95 somatic variants for this specimen: 53 protein-altering or splice-affecting, 32 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 32, Intron 4, Nonsense Mutation 4, 5'UTR 2, 3'UTR 1, 5'Flank 1, 3'Flank 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 300/490 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARSG | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775538549; called by muse, mutect2, varscan2
- ASCL4 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as rs746756373, COSV100661143; called by muse, mutect2, varscan2
- BMP7 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 51/406 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV67780584; called by muse, mutect2, varscan2
- CASP5 | c.484A>T p.I162L | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52827162; called by muse, varscan2
- CDC23 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs767960544; called by muse, mutect2, varscan2
- CHP1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs368755434; called by muse, mutect2, varscan2
- CLEC4A | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1389379274; called by muse, mutect2
- CNOT1 | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1329047920, COSV55316140; called by muse, mutect2, varscan2
- CTAG2 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 94/230 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1557241350, COSV55995959; called by muse, mutect2, varscan2
- CYP1B1 | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as CD091791, CD147585; called by muse, mutect2, varscan2
- CYP24A1 | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 239/654 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.054); catalogued as rs763084124, COSV53775322; called by muse, mutect2, varscan2
- EXOC7 | c.1489G>T p.G497C (on ENST00000335146 / NM_001145297.4; = p.G415C on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 195/432 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58740921; called by muse, mutect2, varscan2
- FOLR1 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 55/428 reads (13%) | catalogued as rs763735285, COSV56616908; called by muse, mutect2, varscan2
- ITIH6 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.772); catalogued as rs148510676; called by muse, mutect2, varscan2
- KCNMB1 | c.377A>T p.K126I | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.478); catalogued as rs199808458; called by muse, mutect2
- LTF | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs199748853; called by muse, mutect2, varscan2
- NCKAP1L | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764565874, COSV53203168; called by muse, mutect2, varscan2
- OR11L1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs536790643, COSV63313548; called by muse, mutect2, varscan2
- PARS2 | c.1256G>A p.G419E | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781329433; called by muse, mutect2, varscan2
- PDXDC1 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1193052108, COSV57911291; called by muse, mutect2, varscan2
- PIGV | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200014772; called by muse, mutect2, varscan2
- PLEKHF1 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs760871091; called by muse, mutect2, varscan2
- SALL1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs757169483; called by muse, mutect2, varscan2
- SASH1 | c.3539C>T p.S1180L | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1401416180; called by muse, mutect2, varscan2
- SIGLEC6 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 64/413 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as rs368576884; called by muse, mutect2, varscan2
- SPEF2 | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs528975025, COSV61551063; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 55/229 reads (24%) | PolyPhen probably damaging (1); catalogued as rs367738862, COSV59565796; called by muse, mutect2, varscan2
- SUGT1 | c.854G>A p.R285K (on ENST00000343788 / NM_001130912.3; = p.R253K on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.163); catalogued as COSV59422344; called by muse, mutect2, varscan2
- TENM2 | c.6352C>T p.R2118C (on ENST00000518659 / NM_001122679.2; = p.R1879C on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs770870348, COSV69123403, COSV69138462; called by muse, mutect2, varscan2
- TP53 | c.192del p.R65Efs*58 | Frame Shift Del (DEL) | VAF 89/225 reads (40%) | catalogued as CD065798; called by mutect2, pindel, varscan2
- WDR1 | c.613G>A p.A205T (on ENST00000382452; = p.A65T on NM_005112.5) | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs1344929229; called by muse, mutect2, varscan2
- WDR64 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.939); catalogued as rs536501700, COSV63794724, COSV63798995; called by muse, mutect2, varscan2
- ABCA5 | c.3344C>G p.S1115* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | called by muse, varscan2
- ANTXRL | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 122/266 reads (46%) | called by muse, mutect2, varscan2
- ARHGAP27 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 249/751 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHN1 | c.411G>C p.M137I | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.145); called by muse, mutect2
- COL6A1 | c.1218A>T p.K406N | Missense Mutation (SNP) | VAF 122/462 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ESRRG | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXD10 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ITPKA | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LGR6 | c.1948G>C p.V650L (on ENST00000367278 / NM_001017403.1; = p.V598L on NM_021636.3) | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.31); called by muse, mutect2
- LRFN1 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MYO19 | c.2494C>A p.L832M (on ENST00000614623 / NM_001163735.1; = p.L632M on NM_025109.5) | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, varscan2
- PDE5A | c.1288G>C p.D430H | Missense Mutation (SNP) | VAF 103/315 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- PSMD12 | c.232A>C p.K78Q | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PXN | c.438C>A p.D146E | Missense Mutation (SNP) | VAF 40/454 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PYROXD1 | c.1340T>A p.I447N | Missense Mutation (SNP) | VAF 264/870 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- RNF19B | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SEPTIN4 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- SMARCA1 | c.516G>C p.E172D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAZ | c.229C>T p.H77Y | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF816 | c.939C>G p.Y313* | Nonsense Mutation (SNP) | VAF 24/390 reads (6%) | called by muse, mutect2
- ADGRF4 | c.339A>T p.P113= | Silent (SNP) | VAF 58/243 reads (24%) | called by muse, mutect2, varscan2
- ATPSCKMT | c.600G>A p.G200= | Silent (SNP) | VAF 115/745 reads (15%) | called by muse, mutect2, varscan2
- C10orf90 | c.1773G>T p.L591= | Silent (SNP) | VAF 307/644 reads (48%) | called by muse, mutect2, varscan2
- C19orf47 | c.390C>T p.G130= | Silent (SNP) | VAF 27/145 reads (19%) | catalogued as rs746475267; called by muse, mutect2, varscan2
- CACNA1H | c.4503A>T p.S1501= | Silent (SNP) | VAF 55/251 reads (22%) | called by muse, mutect2, varscan2
- CERS1 | c.684C>T p.R228= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as rs761091051; called by muse, mutect2, varscan2
- CES3 | c.465C>T p.G155= | Silent (SNP) | VAF 62/115 reads (54%) | catalogued as rs144817489; called by muse, mutect2, varscan2
- DOCK8 | c.4977G>T p.T1659= | Silent (SNP) | VAF 90/315 reads (29%) | catalogued as COSV66620803; called by muse, mutect2, varscan2
- DR1 | c.114G>C p.L38= | Silent (SNP) | VAF 109/426 reads (26%) | called by muse, mutect2, varscan2
- FAM43B | c.966G>A p.R322= | Silent (SNP) | VAF 16/39 reads (41%) | called by muse, varscan2
- GRK7 | c.69G>A p.S23= | Silent (SNP) | VAF 62/174 reads (36%) | catalogued as rs1409696087; called by muse, mutect2, varscan2
- HAMP | c.195C>T p.I65= | Silent (SNP) | VAF 47/864 reads (5%) | catalogued as rs771075802; called by muse, mutect2
- HR | c.2823T>G p.A941= | Silent (SNP) | VAF 144/653 reads (22%) | called by muse, mutect2, varscan2
- JAK2 | c.2289A>G p.L763= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- LGALS7B | c.177G>A p.E59= | Silent (SNP) | VAF 264/898 reads (29%) | catalogued as rs754970885; called by muse, mutect2, varscan2
- MAN2A2 | c.2631G>T p.R877= | Silent (SNP) | VAF 44/266 reads (17%) | called by muse, mutect2, varscan2
- MKRN3 | c.114C>T p.S38= | Silent (SNP) | VAF 53/400 reads (13%) | catalogued as rs143204731, COSV100090930; called by muse, mutect2, varscan2
- MYO16 | c.4935G>A p.A1645= | Silent (SNP) | VAF 48/274 reads (18%) | catalogued as COSV100697003, COSV62758718; called by muse, mutect2, varscan2
- NOG | c.594G>A p.V198= | Silent (SNP) | VAF 35/61 reads (57%) | called by muse, mutect2, varscan2
- NTRK2 | c.1689G>A p.E563= (on ENST00000323115 / NM_001369534.1; = p.E579= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/358 reads (23%) | called by muse, mutect2, varscan2
- PARD6G | c.1078C>T p.L360= | Silent (SNP) | VAF 39/190 reads (21%) | catalogued as rs927673676, COSV62061010; called by muse, mutect2, varscan2
- PIK3R5 | c.1602G>A p.A534= | Silent (SNP) | VAF 102/406 reads (25%) | catalogued as rs200430963; called by muse, mutect2, varscan2
- ROCK1 | c.996C>A p.I332= | Silent (SNP) | VAF 234/397 reads (59%) | called by muse, mutect2, varscan2
- SLC30A4 | c.81C>T p.S27= | Silent (SNP) | VAF 134/369 reads (36%) | catalogued as rs749499477; called by muse, mutect2, varscan2
- SPATA31D1 | c.4500G>A p.Q1500= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs1443248843; called by muse, mutect2, varscan2
- STAC3 | c.1074C>G p.T358= | Silent (SNP) | VAF 88/341 reads (26%) | catalogued as COSV60414798; called by muse, mutect2, varscan2
- TDRD1 | c.1722C>T p.V574= | Silent (SNP) | VAF 91/194 reads (47%) | catalogued as rs201880270; called by muse, mutect2, varscan2
- TENM4 | c.5721C>T p.Y1907= | Silent (SNP) | VAF 73/239 reads (31%) | catalogued as rs768735704, COSV53625388; called by muse, mutect2, varscan2
- TIE1 | c.333G>A p.A111= | Silent (SNP) | VAF 75/318 reads (24%) | catalogued as rs774340072, COSV65249562; called by muse, mutect2, varscan2
- TUT1 | c.69T>C p.V23= | Silent (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- WDR97 | c.1419G>A p.P473= | Silent (SNP) | VAF 71/357 reads (20%) | catalogued as rs1360010785; called by muse, mutect2, varscan2
- ZNF211 | c.66G>T p.A22= | Silent (SNP) | VAF 77/202 reads (38%) | called by muse, mutect2, varscan2
- EIF2B4 | c.*33T>G | 3'UTR (SNP) | VAF 144/333 reads (43%) | catalogued as rs1247859477; called by muse, mutect2, varscan2
- EIF2B4 | c.32-37C>T | Intron (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- FCRL6 | c.-26C>T | 5'UTR (SNP) | VAF 102/246 reads (41%) | called by muse, mutect2, varscan2
- HES6 | chr2:238240637 del C | 5'Flank (DEL) | VAF 37/150 reads (25%) | called by mutect2, pindel, varscan2
- MARCHF1 | c.242+918C>A | Intron (SNP) | VAF 30/193 reads (16%) | called by muse, mutect2, varscan2
- MRPL10 | c.52+32C>T | Intron (SNP) | VAF 65/392 reads (17%) | catalogued as rs1333324433; called by muse, mutect2, varscan2
- POM121C | chr7:75416000 del G | 3'Flank (DEL) | VAF 142/336 reads (42%) | called by mutect2, varscan2
- TEX21P | n.1336A>G | RNA (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- THBS2 | c.-11C>T | 5'UTR (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- TNS1 | c.-55+914C>T | Intron (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
